Somatic mutation profile of tumor specimen C3L-03388-02 (aliquot CPT0239910007) from CPTAC case C3L-03388, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 68.1 years (24,887 days).
Specimen C3L-03388-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72b8ee53-494c-4c75-b756-c98a6ef3bb3a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03388-31 (Blood Derived Normal), aliquot CPT0240550002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96eade5f-b42d-431d-b344-758da0a3e349

The open-access MAF lists 39 somatic variants for this specimen: 25 protein-altering or splice-affecting, 8 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 8, Intron 4, Nonsense Mutation 2, 5'UTR 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 91/1116 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 78/461 reads (17%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as rs587782529, CM981929, COSV52669243, COSV52718762, COSV52810068, COSV52816817; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.4375G>A p.V1459I | Missense Mutation (SNP) | VAF 46/224 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs752169862, COSV52639459; called by muse, mutect2, varscan2
- ASCC3 | c.1754C>T p.P585L | Missense Mutation (SNP) | VAF 40/409 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100225163; called by muse, mutect2
- CACNA1S | c.933G>T p.W311C | Missense Mutation (SNP) | VAF 257/761 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62944845; called by muse, mutect2, varscan2
- CST8 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 48/300 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.782); catalogued as rs750316947; called by muse, mutect2
- DNAH8 | c.1645G>A p.A549T | Missense Mutation (SNP) | VAF 49/361 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV59426631; called by muse, mutect2, varscan2
- HAUS1 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 32/242 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as rs749832789, COSV99959528; called by muse, varscan2
- MAN2C1 | c.1879G>A p.V627I | Missense Mutation (SNP) | VAF 80/409 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs748277033, COSV51228106; called by muse, mutect2, varscan2
- NEXMIF | c.4346G>A p.R1449H | Missense Mutation (SNP) | VAF 65/283 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778760434, COSV50022011, COSV50029019; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR5AC2 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 18/329 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100684402; called by muse, mutect2
- PRAMEF19 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 60/766 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs1388182105; called by muse, mutect2
- RBM10 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 163/501 reads (33%) | catalogued as COSV61311469; called by muse, mutect2, varscan2
- SLC5A11 | c.455T>C p.I152T | Missense Mutation (SNP) | VAF 65/356 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs761238809; called by muse, mutect2, varscan2
- ULK4 | c.1886T>C p.I629T | Missense Mutation (SNP) | VAF 42/279 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs980545512; called by muse, mutect2, varscan2
- ACOT12 | c.215C>T p.T72I | Missense Mutation (SNP) | VAF 62/462 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DLG5 | c.2179C>T p.Q727* | Nonsense Mutation (SNP) | VAF 77/621 reads (12%) | called by muse, mutect2, varscan2
- FMO2 | c.1201T>G p.S401A | Missense Mutation (SNP) | VAF 16/396 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.511); called by muse, mutect2
- NR3C1 | c.2173A>T p.M725L | Missense Mutation (SNP) | VAF 10/350 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2
- RYR1 | c.7117G>T p.G2373C | Missense Mutation (SNP) | VAF 20/599 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- STK11 | c.224_226del p.R75_A76delinsT | In Frame Del (DEL) | VAF 45/286 reads (16%) | called by mutect2, pindel, varscan2
- SULT4A1 | c.823A>C p.K275Q | Missense Mutation (SNP) | VAF 54/295 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- TFAP2C | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 88/580 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- WDPCP | c.726G>T p.W242C | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF667 | c.457T>A p.F153I | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ADAM9 | c.960A>G p.T320= | Silent (SNP) | VAF 32/862 reads (4%) | called by muse, mutect2
- ARHGAP32 | c.5454C>T p.A1818= (on ENST00000310343 / NM_001378025.1; = p.A1469= on NM_014715.4) | Silent (SNP) | VAF 89/701 reads (13%) | called by muse, mutect2, varscan2
- COL24A1 | c.4197T>C p.G1399= | Silent (SNP) | VAF 16/176 reads (9%) | catalogued as rs1207619238; called by muse, mutect2
- FAM71A | c.1722G>T p.G574= | Silent (SNP) | VAF 47/347 reads (14%) | called by muse, mutect2, varscan2
- OR52M1 | c.429G>A p.V143= | Silent (SNP) | VAF 20/179 reads (11%) | catalogued as COSV100798599, COSV64173021; called by muse, mutect2, varscan2
- POLR2M | c.600C>T p.T200= | Silent (SNP) | VAF 136/563 reads (24%) | called by muse, mutect2, varscan2
- SLC1A6 | c.1002C>A p.V334= | Silent (SNP) | VAF 17/323 reads (5%) | catalogued as COSV99693610; called by muse, mutect2
- ZNRF4 | c.627C>T p.I209= | Silent (SNP) | VAF 88/488 reads (18%) | called by muse, mutect2, varscan2
- CLASP1 | c.2018-30C>G | Intron (SNP) | VAF 77/512 reads (15%) | called by muse, mutect2, varscan2
- FBXL13 | c.-1+490G>A | Intron (SNP) | VAF 20/280 reads (7%) | catalogued as COSV57542752; called by muse, mutect2
- MIR337 | n.30T>C | RNA (SNP) | VAF 54/325 reads (17%) | called by muse, mutect2, varscan2
- RAPGEF5 | c.-15C>T | 5'UTR (SNP) | VAF 7/62 reads (11%) | catalogued as rs1403138345; called by muse, mutect2, varscan2
- RHOT1 | c.1739+2917C>A | Intron (SNP) | VAF 19/115 reads (17%) | called by muse, mutect2, varscan2
- SPTBN4 | c.5084+127C>A | Intron (SNP) | VAF 14/84 reads (17%) | called by muse, mutect2, varscan2
